Somatic mutation profile of tumor specimen MP2PRT-PATYAT-TMP1-A (aliquot MP2PRT-PATYAT-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PATYAT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,661 days).
Specimen MP2PRT-PATYAT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c45d45d-c9ac-4b63-b62d-aa579a2fa5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATYAT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATYAT-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2761a9fa-1c4d-417b-a639-823ebde9d0e4

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP7 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 63/642 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs778545569, CM1210279, COSV60172027; called by muse, mutect2, varscan2
- NRCAM | c.3034C>T p.R1012W (on ENST00000379028 / NM_001371124.1; = p.R996W on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs200175819; called by muse, mutect2, varscan2
- PIK3C2G | c.3424C>T p.R1142C (on ENST00000676171; = p.R1101C on NM_004570.5) | Missense Mutation (SNP) | VAF 111/305 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs756366407, COSV56819673; called by muse, mutect2, varscan2
- CAT | c.565C>A p.R189S | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FOXP2 | c.1942T>C p.S648P | Missense Mutation (SNP) | VAF 142/321 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGKV3-15 | chr2:89085172 GTGGGAG>TTGAGGAGAA | Missense Mutation (INS) | VAF 54/199 reads (27%) | called by pindel, varscan2*
- SNRNP70 | c.310_311insGG p.T104Rfs*8 | Frame Shift Ins (INS) | VAF 57/258 reads (22%) | called by mutect2, pindel, varscan2
- ORMDL2 | c.12G>A p.G4= | Silent (SNP) | VAF 75/202 reads (37%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26673216 C>T | 3'Flank (SNP) | VAF 119/328 reads (36%) | catalogued as rs894875390; called by muse, mutect2, varscan2
